Gene-level copy-number profile of specimen HCM-CSHL-0248-C19-85A from HCMI case HCM-CSHL-0248-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 53.4 years (19,501 days).
Specimen HCM-CSHL-0248-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0b2e4343-8237-4c03-8aa6-268f1907f2c9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0248-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/3d9c23af-5851-476e-9d75-6a298f6e3e68

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 130; copy number 2: 26,620; copy number 3: 21,990; copy number 4: 6,896; copy number 5: 1,301; copy number 6: 1,461; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:7,126,293–7,126,639, 1 gene (within-gene range 0–2): AC022206.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,766 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–45,098,647, 675 genes, copy number 5–6 (broad region; genes not listed).
- chr9:135,693,407–137,870,016, 127 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:42,149,310–46,537,864, 127 genes, copy number 5–7 (broad region; genes not listed).
- chr10:123,666,355–133,778,699, 174 genes, copy number 5–6 (broad region; genes not listed).
- chr11:86,649–87,586, 1 gene, copy number 6: OR4F2P.
- chr12:12,310–6,124,770, 136 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:6,199,715–6,709,552, 38 genes, copy number 5: CD9, Y_RNA, ATP5MFP5, PLEKHG6, TNFRSF1A, RN7SL391P, SCNN1A, LTBR, AC005840.2, AC005840.1, SRP14P1, CD27-AS1, CD27, TAPBPL, VAMP1, AC005840.4, AC005840.3, MRPL51, NCAPD2, SCARNA10, AC006064.5, AC006064.3, GAPDH, AC006064.4, IFFO1, AC006064.1, NOP2, AC006064.6, CHD4, AC006064.2, SCARNA11, LPAR5, ACRBP, ING4, AC125494.1, ZNF384, PIANP, RNU6-781P.
- chr12:10,824,960–11,171,608, 1 gene, copy number 5 (within-gene range 4–5): PRH1.
- chr12:10,845,849–11,251,389, 23 genes, copy number 5 (within-gene range 4–5): PRR4, AC018630.4, AC006518.2, TAS2R13, PRH2, TAS2R14, TAS2R15P, TAS2R50, TAS2R20, TAS2R19, TAS2R31, TAS2R63P, TAS2R46, TAS2R64P, TAS2R43, AC018630.1, TAS2R30, AC134349.2, AC134349.1, SMIM10L1, TAS2R42, AC244131.1, AC244131.2.
- chr12:11,307,077–11,895,377, 13 genes, copy number 5: PRB4, PRB1, PRB2, AC078950.1, HIGD1AP8, AC007450.4, AC007450.3, DDX55P1, AC007450.2, AC007450.1, RNU7-60P, LINC01252, ETV6.
- chr12:12,357,078–12,984,645, 26 genes, copy number 5 (within-gene range 4–5): BORCS5, AC007619.2, DUSP16, AC007619.1, AC092824.1, CREBL2, RPL21P136, AC008115.4, GPR19, AC008115.2, CDKN1B, AC008115.3, AC008115.1, APOLD1, MIR613, STX8P1, DDX47, AC007215.1, AC007688.2, RPL13AP20, GPRC5A, MIR614, GPRC5D-AS1, GPRC5D, AC007688.3, AC007688.1.
- chr12:13,044,381–14,567,883, 22 genes, copy number 5 (within-gene range 4–5): FAM234B, GSG1, EMP1, LINC01559, GRIN2B, RNA5SP353, RNU6-590P, AC007527.1, AC007527.2, AC007535.1, RN7SKP162, AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134.
- chr12:14,612,632–16,037,381, 28 genes, copy number 5 (within-gene range 4–5): GUCY2C, AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1, PTPRO, AC092183.1, EPS8, RNU6-251P, AC073651.1, AC073651.2, STRAP, DERA.
- chr12:16,188,485–16,788,375, 9 genes, copy number 5: SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1.
- chr12:26,121,991–26,299,290, 1 gene, copy number 5 (within-gene range 4–5): SSPN.
- chr12:26,139,249–27,325,959, 23 genes, copy number 5: AC022509.5, AC022509.2, AC022509.1, AC022509.4, AC055720.1, AC055720.3, AC024145.1, ITPR2, AC055720.2, RNA5SP354, AC023051.1, AC023051.2, INTS13, FGFR1OP2, TM7SF3, AC024896.1, MED21, AC092747.4, C12orf71, AC092747.3, AC092747.1, AC092747.2, STK38L.
- chr12:27,466,810–27,710,803, 11 genes, copy number 5 (within-gene range 4–5): SMCO2, RARS1P1, PPFIBP1, AC087257.1, AC087257.2, AC009509.3, AC009509.1, REP15, AC009509.4, HMGB1P49, AC009509.2.
- chr12:32,396,050–32,396,147, 1 gene, copy number 5: Y_RNA.
- chr13:18,467,172–114,337,626, 1,330 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 130. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
